Surgical pathology report (de-identified scan), TCGA case TCGA-KM-8639, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-8639-01A (Primary Tumor).

[page 1 of 3]
MEDICAL RECORD**Surgical Pathology Report****Surgical Pathology Report****PATIENT:****ACCOUNT#:****DOB:****AGE:****SEX:****ATTENDING:****REQUESTING:****CONTACT NO: (MD) -****COPIES TO:****MRN:****RECEIVED DATE:****PROCEDURE DATE:****SIGN-OUT DATE:****LOCATION:****ROOM:**

DIAGNOSIS: Kidney, right (total nephrectomy): Renal cell carcinoma, chromophobe cell type, Fuhrman nuclear grade II of IV, see Note.

-Tumor does not involve surgical margins or ureteral and vascular margins.

-Nephrosclerosis and moderate atherosclerosis involving the renal artery.

NOTE:**Kidney Nephrectomy Summary Table****Macroscopic****Specimen Type:** Radical nephrectomy**Laterality:>** right**Tumor Size:** 2.1cm**Focality:** unifocal**Macro Extent of Tumor:** tumor limited to kidney**Microscopic****Histologic Type:** chromophobe**Histologic Grade:** G2**Extent of Invasion****Primary Tumor(pT):** pT1a**Regional Lymph Nodes(pN):**pNX**Distant Metastasis(pM):** pMX**Margins:** uninvolved by carcinoma**CLINICAL INFORMATION:** Brief Clinical History: pt with right renal mass Specimen Taken For Protocol:

Requestor Name Requestor Phone/Pager: Admitting Protocol Number:

PROCEDURE: Pre-Operative Diagnosis: right renal mass Post-Operative Diagnosis: right renal mass Operative

Patient Identification

[page 2 of 3]
MEDICAL RECORD**Surgical Pathology Report****Name:**
MRN:**Accession No.:**
Date of Report:

Findings: right renal mass

SPECIMENS SUBMITTED: KIDNEY, RIGHT, And Gerota's fascia

GROSS DESCRIPTION: The specimen is received in a single container labeled with the patient's name, medical record number, and "right kidney and Gerota's fascia". The specimen consists of a nephrectomy weighing 215.1 grams and measuring 12 x 10 x 4 cm in dimension. No palpable mass is present. The surgical margin is inked in black and bivalved via the antehilar surface to reveal a kidney-colored nodule measuring 2.1 x 1.5 cm at the corticomedullary junction. The tumor is greater than 2 cm from the closest surgical margin and is well circumscribed. A 1 x 1 cm piece of nodule and a 1 x 1 cm piece of normal-appearing parenchyma is procured for UOB. Photographs have been taken of the case. The procurement was performed by [REDACTED]. In Surgical Pathology, the specimen is received in a formalin-filled container. The specimen has been previously bivalved and half of the tumor has been shelled out. The remainder of the tumor is located at the corticomedullary junction. Cut sectioning of the tumor demonstrates a brownish, normal-appearing kidney parenchyma surrounding the nodular tan-brown tumor mass. Deep to the tumor within the cortex is a clear fluid-filled cortical cyst. On half of the kidney which was previously procured, the tumor appears to infiltrate into the normal-appearing kidney parenchyma with pushing borders in a very thin white capsule surrounding the tumor from the normal kidney. The tumor does not appear to involve the hilum and is 0.3 cm from the hilar edge of the kidney, and 0.4 cm from the perinephric fat. The vascular and ureteral margins are grossly free of tumor. Sectioning through the remainder of the kidney demonstrates brown-tan, unremarkable kidney parenchyma with no additional nodules or mass is seen. There is no perinephric fat surrounding the capsule of the kidney deep to the tumor nodule. Sectioning through the hilar fat demonstrates no lymph node candidates. Analysis of the renal artery demonstrates an area of atherosclerosis which is approximately 60% occluded. There are no additional nodules or masses seen in the perinephric fat.

Representative sections are submitted as follows:

- 1 A-C - tumor at closest surgical margin and hilum
- 1 D - vascular and ureteral margin
- E - normal kidney parenchyma
- F - atherosclerotic blood vessel cross-section

Gross dictated by [REDACTED]

Patient Identification

Surgical Pathology Report

File in Section 3: Tissue Examination

Page 2

[page 3 of 3]
[REDACTED]

Name:	Accession No.:
MRN:	Date of Report: [REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 9abbc853-40e7-4d51-8730-ae032861dd51 (TCGA-KM-8639.22DB1914-7524-48CD-8059-AF661C35C5A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).